CCDI case PBCIPI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3053fe91-8982-44d3-b092-61ca2dd7b201

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.5 years (4,198 days).

Biospecimens (2 samples)
- Sample 0DSWZ2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSWZ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
